CCDI case PBBZDH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/cc9d54df-9ec8-49c5-be52-1774cf4a98a0

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.5 years (553 days).

Biospecimens (3 samples)
- Sample 0DLA12: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLA20: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DLA2W: Tissue type: Tumor; Specimen type: Solid Tissue.
